Somatic mutation profile of tumor specimen C3N-00320-03 (aliquot CPT0012380009) from CPTAC case C3N-00320, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.3 years (24,594 days).
Specimen C3N-00320-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fc49ab3-8910-413b-b7d1-8209b48e863b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00320-31 (Blood Derived Normal), aliquot CPT0012530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c42b008b-685e-44df-af95-c652225e1e54

The open-access MAF lists 126 somatic variants for this specimen: 88 protein-altering or splice-affecting, 24 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 24, Intron 10, Frame Shift Del 8, In Frame Del 5, Nonsense Mutation 4, Splice Site 2, 3'UTR 2, 5'UTR 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4447T>C p.C1483R | Missense Mutation (SNP) | VAF 60/99 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1057519914, COSV63875155; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NOTCH3 | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 153/397 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs28937321, CM961042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.340+2T>A p.X114_splice | Splice Site (SNP) | VAF 155/249 reads (62%) | hotspot (GDC flag); catalogued as CD983001, COSV56547957, COSV56551654, COSV56551713, COSV56563827; called by muse, mutect2, varscan2
- ADGRA1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs755811625, COSV74142839; called by muse, mutect2, varscan2
- AL035078.4 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs749117053; called by muse, mutect2, varscan2
- ANLN | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs1197927402; called by muse, mutect2
- ATP13A1 | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99366716; called by muse, mutect2, varscan2
- BECN1 | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV100831112; called by muse, mutect2, varscan2
- BICRA | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs1318644811, COSV67603580; called by muse, mutect2, varscan2
- COL24A1 | c.3325C>A p.P1109T | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV65313975; called by muse, mutect2, varscan2
- FBLN1 | c.1225C>A p.R409S | Missense Mutation (SNP) | VAF 277/764 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1218807619; called by muse, mutect2, varscan2
- HIP1R | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53441598, COSV53442271; called by muse, mutect2, varscan2
- IQGAP3 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs749818611; called by muse, mutect2, varscan2
- KIAA1671 | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1273660436, COSV64450632; called by muse, mutect2, varscan2
- MAN2B2 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs757830667, COSV53450411, COSV99577991; called by muse, mutect2, varscan2
- PCDH7 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688654; called by muse, mutect2, varscan2
- PDE8B | c.2185A>G p.M729V | Missense Mutation (SNP) | VAF 200/581 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs757855600; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1005G>T p.M335I | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1373615174, COSV65048947; called by muse, mutect2
- PRKG1 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773713867; called by muse, mutect2, varscan2
- PRPF40B | c.2053-4C>G | Splice Region (SNP) | VAF 55/162 reads (34%) | catalogued as rs1460701180; called by muse, mutect2, varscan2
- RABEP2 | c.555del p.H186Mfs*28 | Frame Shift Del (DEL) | VAF 44/158 reads (28%) | catalogued as COSV100706746; called by mutect2, pindel, varscan2
- UGT1A7 | c.671dup p.K225Qfs*9 | Frame Shift Ins (INS) | VAF 131/484 reads (27%) | catalogued as rs1476036720; called by pindel, varscan2
- VARS1 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763964925, COSV65155616; called by muse, mutect2, varscan2
- ZNF541 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 166/484 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV54545132; called by muse, mutect2, varscan2
- ACTR3C | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- AK4 | c.355_357del p.L119del | In Frame Del (DEL) | VAF 25/116 reads (22%) | called by mutect2, pindel, varscan2
- AK7 | c.1455G>C p.K485N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ANKDD1A | c.1425_1433del p.E475_S478delinsD | In Frame Del (DEL) | VAF 55/340 reads (16%) | called by mutect2, pindel, varscan2
- APBB3 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- BMP2K | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- C2CD3 | c.3044G>A p.G1015E | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNB2 | c.1042A>G p.R348G (on ENST00000324631 / NM_201596.3; = p.R293G on NM_000724.4) | Missense Mutation (SNP) | VAF 131/374 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CACNB2 | c.1043G>A p.R348K (on ENST00000324631 / NM_201596.3; = p.R293K on NM_000724.4) | Missense Mutation (SNP) | VAF 129/366 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CAMKK1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAPS2 | c.1121del p.L374* | Frame Shift Del (DEL) | VAF 106/359 reads (30%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1724C>A p.A575D | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CCDC168 | c.9328C>A p.H3110N | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC96 | c.973_978del p.K325_E326del | In Frame Del (DEL) | VAF 30/102 reads (29%) | called by mutect2, pindel, varscan2
- CCL11 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELF2 | c.1043C>G p.T348S (on ENST00000416382 / NM_001025077.3; = p.T355S on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLIP1 | c.2065G>T p.A689S (on ENST00000620786 / NM_001247997.1; = p.A678S on NM_002956.2) | Missense Mutation (SNP) | VAF 133/298 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL4A2 | c.2959A>T p.K987* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- CR1 | c.3712C>A p.L1238M | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CRELD1 | c.501_503delinsT p.Q168Vfs*2 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | called by pindel, varscan2*
- CSMD1 | c.2720G>T p.S907I (on ENST00000520002; = p.S906I on NM_033225.6) | Missense Mutation (SNP) | VAF 107/281 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DGCR2 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNM1P46 | n.469C>T | Splice Region (SNP) | VAF 76/352 reads (22%) | called by muse, mutect2
- ELP3 | c.1187T>A p.I396K | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHB3 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ERMAP | c.1214del p.N405Tfs*5 | Frame Shift Del (DEL) | VAF 69/207 reads (33%) | called by mutect2, pindel, varscan2
- GOLGA8H | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 355/997 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GRIN2D | c.651C>A p.H217Q | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- HDHD5 | c.637C>G p.L213V (on ENST00000336737 / NM_033070.3; = p.L183V on NM_017829.5) | Missense Mutation (SNP) | VAF 110/275 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- HIP1R | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS14 | c.748+1G>A p.X250_splice (on ENST00000313182 / NM_001366360.2; = p.X171_splice on NM_001136043.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 84/149 reads (56%) | called by muse, varscan2
- KAT2A | c.2306T>C p.I769T | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIN54 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC5B | c.7784C>A p.T2595N | Missense Mutation (SNP) | VAF 199/525 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MYH3 | c.2963A>T p.E988V | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MYH3 | c.2962G>T p.E988* | Nonsense Mutation (SNP) | VAF 85/257 reads (33%) | called by muse, mutect2, varscan2
- NELL2 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NEO1 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPTN | c.49_51del p.S17del | In Frame Del (DEL) | VAF 99/372 reads (27%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1450A>T p.K484* | Nonsense Mutation (SNP) | VAF 79/124 reads (64%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDE8B | c.445T>C p.W149R | Missense Mutation (SNP) | VAF 157/359 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAD50 | c.3817_3821del p.F1273Gfs*7 | Frame Shift Del (DEL) | VAF 79/241 reads (33%) | called by mutect2, pindel, varscan2
- RECK | c.945T>A p.N315K | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RECK | c.1723A>T p.I575L | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCAF4 | c.2341A>G p.I781V | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGCZ | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SLC35D2 | c.877del p.I293Ffs*5 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | called by mutect2, pindel, varscan2
- SPIN3 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 99/126 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNGAP1 | c.2786A>T p.N929I | Missense Mutation (SNP) | VAF 140/396 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TASOR2 | c.3746del p.N1249Ifs*2 | Frame Shift Del (DEL) | VAF 73/223 reads (33%) | called by mutect2, pindel, varscan2
- TBC1D12 | c.1283_1291del p.A428_R431delinsG | In Frame Del (DEL) | VAF 44/98 reads (45%) | called by mutect2, pindel, varscan2
- TBC1D9 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THAP3 | c.381G>T p.M127I (on ENST00000054650 / NM_001195753.1; = p.M134I on NM_138350.3) | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- TMCO5A | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TOMM34 | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 65/162 reads (40%) | called by muse, mutect2, varscan2
- TTI2 | c.1139A>T p.H380L | Missense Mutation (SNP) | VAF 178/489 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC80 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 167/456 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP28 | c.2470C>G p.R824G | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY3 | c.8669del p.F2890Sfs*14 | Frame Shift Del (DEL) | VAF 57/175 reads (33%) | called by mutect2, pindel, varscan2
- WIZ | c.4203G>T p.M1401I (on ENST00000673675 / NM_001371589.1; = p.M306I on NM_021241.3) | Missense Mutation (SNP) | VAF 170/367 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ZC3H7A | c.1892A>T p.Q631L | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ZFR | c.1572A>T p.E524D | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF724 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- CAMKK1 | c.1509T>A p.A503= | Silent (SNP) | VAF 85/257 reads (33%) | called by muse, mutect2, varscan2
- CEP76 | c.1401A>T p.G467= | Silent (SNP) | VAF 81/253 reads (32%) | called by muse, mutect2, varscan2
- COL24A1 | c.3324T>C p.I1108= | Silent (SNP) | VAF 52/182 reads (29%) | called by muse, mutect2, varscan2
- CRACR2B | c.180C>T p.D60= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as rs1364287808; called by muse, mutect2, varscan2
- DLX6 | c.751C>T p.L251= | Silent (SNP) | VAF 185/529 reads (35%) | catalogued as rs1225120437; called by muse, mutect2, varscan2
- DQX1 | c.1123C>A p.R375= | Silent (SNP) | VAF 83/224 reads (37%) | catalogued as rs150420269; called by muse, mutect2, varscan2
- DYRK1A | c.816A>G p.A272= | Silent (SNP) | VAF 119/370 reads (32%) | catalogued as COSV100117899; called by muse, mutect2, varscan2
- EEF2KMT | c.993G>A p.*331= | Silent (SNP) | VAF 92/287 reads (32%) | catalogued as rs1337048855; called by muse, mutect2, varscan2
- EPHB2 | c.1476G>A p.T492= | Silent (SNP) | VAF 206/348 reads (59%) | catalogued as rs370664820; called by muse, mutect2, varscan2
- FCGBP | c.4830G>T p.T1610= | Silent (SNP) | VAF 123/836 reads (15%) | called by muse, mutect2, varscan2
- ITGAD | c.1269C>T p.A423= | Silent (SNP) | VAF 66/244 reads (27%) | catalogued as COSV66760153; called by muse, mutect2, varscan2
- KAT6A | c.4482C>T p.V1494= | Silent (SNP) | VAF 79/204 reads (39%) | catalogued as COSV55904223; called by muse, mutect2, varscan2
- KCNH5 | c.1923C>T p.I641= | Silent (SNP) | VAF 87/147 reads (59%) | catalogued as COSV59768828; called by muse, mutect2, varscan2
- LRP1B | c.5394C>T p.A1798= | Silent (SNP) | VAF 108/296 reads (36%) | catalogued as rs754226036; called by muse, mutect2, varscan2
- OR4C6 | c.651G>T p.T217= | Silent (SNP) | VAF 128/392 reads (33%) | catalogued as rs776795154, COSV58605361, COSV58606268; called by muse, mutect2, varscan2
- PRMT7 | c.1095G>T p.V365= | Silent (SNP) | VAF 119/375 reads (32%) | called by muse, mutect2, varscan2
- RBP3 | c.621C>T p.T207= | Silent (SNP) | VAF 283/487 reads (58%) | called by muse, mutect2, varscan2
- SIKE1 | c.549A>G p.L183= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as rs963804130; called by muse, mutect2, varscan2
- STAC2 | c.150G>A p.E50= | Silent (SNP) | VAF 107/316 reads (34%) | called by muse, mutect2, varscan2
- TCAF2 | c.2759A>G p.*920= (on ENST00000441159 / NM_001363538.2; = p.*816= on NM_001130026.2) | Silent (SNP) | VAF 14/33 reads (42%) | called by mutect2, varscan2
- TCFL5 | c.744T>C p.A248= | Silent (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- WTAP | c.996C>A p.L332= | Silent (SNP) | VAF 99/162 reads (61%) | called by muse, mutect2, varscan2
- ZBTB6 | c.627C>T p.D209= | Silent (SNP) | VAF 49/133 reads (37%) | called by muse, mutect2, varscan2
- ZNF616 | c.447T>A p.A149= | Silent (SNP) | VAF 77/220 reads (35%) | called by muse, mutect2, varscan2
- B4GALT4 | c.*325A>T | 3'UTR (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- CCT6A | c.-33A>G | 5'UTR (SNP) | VAF 80/226 reads (35%) | called by muse, mutect2, varscan2
- CFAP410 | c.643-236C>T | Intron (SNP) | VAF 91/235 reads (39%) | catalogued as rs748118167; called by muse, mutect2, varscan2
- FGFR3 | c.*755C>A | 3'UTR (SNP) | VAF 108/284 reads (38%) | called by muse, mutect2, varscan2
- FNTA | c.783-47del | Intron (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- FSD1L | c.441+43dup | Intron (INS) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- IL12A | c.-25_-5del | 5'UTR (DEL) | VAF 72/257 reads (28%) | called by mutect2, pindel, varscan2
- KIF1B | c.2115+5993G>T | Intron (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2
- KIF1B | c.2115+5994A>G | Intron (SNP) | VAF 16/150 reads (11%) | catalogued as rs376929489; called by muse, mutect2
- MALRD1 | c.5030-2396G>T | Intron (SNP) | VAF 75/198 reads (38%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85983_-322-85980del | Intron (DEL) | VAF 110/302 reads (36%) | called by pindel, varscan2
- NBAS | c.3257+539T>A | Intron (SNP) | VAF 59/178 reads (33%) | called by muse, mutect2, varscan2
- RHOQ | c.202-15459_202-15446del | Intron (DEL) | VAF 39/131 reads (30%) | called by mutect2, pindel, varscan2
- SEPSECS | c.1211+37T>A | Intron (SNP) | VAF 86/247 reads (35%) | called by muse, mutect2, varscan2
